Somatic mutation profile of tumor specimen TCGA-AA-3548-01A (aliquot TCGA-AA-3548-01A-01D-1953-10) from TCGA case TCGA-AA-3548, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 71.7 years (26,175 days).
Specimen TCGA-AA-3548-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30baccc3-7d29-4d41-9630-1602716c289d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3548-10A (Blood Derived Normal), aliquot TCGA-AA-3548-10A-01D-1953-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b889a3de-691d-4cdd-ac0b-c99b430932cd

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 13, Silent 8, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 76/190 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANAPC11 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 110/294 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs535288823, COSV100325980; called by muse, mutect2, varscan2
- ATP2C2 | c.1504-1G>C p.X502_splice | Splice Site (SNP) | VAF 58/221 reads (26%) | catalogued as COSV52296073, COSV99298096; called by muse, mutect2, varscan2
- BSX | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58005960; called by muse, mutect2, varscan2
- CELSR1 | c.3200G>A p.R1067Q | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); catalogued as rs752742697, COSV53098965; called by muse, mutect2, varscan2
- CEP83 | c.2083G>T p.E695* | Nonsense Mutation (SNP) | VAF 183/743 reads (25%) | catalogued as COSV51574268, COSV99313165; called by muse, mutect2, varscan2
- CRACDL | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 145/420 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as rs775019973, COSV67407590, COSV67409395, COSV67410310; called by muse, mutect2, varscan2
- DAOA | c.209T>C p.L70S | Missense Mutation (SNP) | VAF 262/640 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as rs1433167115, COSV100298765; called by muse, mutect2, varscan2
- DSCAM | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 201/520 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs369442382, COSV101260693; called by muse, mutect2, varscan2
- HECW1 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV67837014; called by muse, mutect2, varscan2
- ITGB4 | c.2098G>A p.V700M | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99564057; called by muse, varscan2
- PIK3CD | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as rs760642664, COSV100740205; called by muse, mutect2, varscan2
- RHOT2 | c.1537A>C p.M513L | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV99558746; called by muse, mutect2, varscan2
- RXFP3 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100347316; called by muse, mutect2, varscan2
- WNT5B | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1262622082, COSV100148689; called by muse, mutect2, varscan2
- ADAMTS16 | c.3375C>T p.P1125= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV99941313; called by muse, mutect2, varscan2
- ELOA2 | c.1428G>A p.P476= | Silent (SNP) | VAF 55/97 reads (57%) | catalogued as rs767997205, COSV99796676; called by muse, mutect2, varscan2
- KCND1 | c.867C>T p.G289= | Silent (SNP) | VAF 43/122 reads (35%) | catalogued as rs1360413880, COSV99501996; called by muse, mutect2, varscan2
- KLHL38 | c.150C>T p.N50= | Silent (SNP) | VAF 46/124 reads (37%) | catalogued as rs968775082, COSV58086332, COSV58088851; called by muse, mutect2, varscan2
- PCDHA2 | c.1812C>T p.N604= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs1554120103, COSV65366812; called by muse, mutect2, varscan2
- PRTG | c.255C>T p.I85= | Silent (SNP) | VAF 147/242 reads (61%) | catalogued as COSV66836830; called by muse, mutect2, varscan2
- SYNGR1 | c.588C>T p.Y196= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as rs143119099; called by muse, mutect2, varscan2
- TEKT2 | c.892C>A p.R298= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV99255526; called by muse, mutect2, varscan2
